Gene-level copy-number profile of tumor specimen TCGA-BR-7901-01A from TCGA case TCGA-BR-7901, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 74.0 years (27,031 days).
Specimen TCGA-BR-7901-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.37997a33-032b-43c5-aa76-d35c5d21db83.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,684 have no estimate.
https://portal.gdc.cancer.gov/files/7a8eb843-d81f-4283-bd3f-107aadbcdb0d

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 243; copy number 1: 2; copy number 2: 91; copy number 3: 8,103; copy number 4: 21,666; copy number 5: 15,410; copy number 6: 2,311; copy number 7: 7,113.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7901-01A-11D-2200-01): tumor purity 0.31, ploidy 4.69, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 243 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:9,442,060–9,442,380, 1 gene: RN7SL5P.
- chr12:1,970,786–2,697,950, 1 gene (within-gene range 0–7): CACNA1C.
- chr12:2,217,462–2,691,200, 9 genes: AC005344.1, CACNA1C-AS4, CACNA1C-IT3, AC005293.1, AC005414.1, CACNA1C-AS3, AC007618.1, CACNA1C-AS2, CACNA1C-AS1.
- chr12:4,097,451–4,615,302, 13 genes: HSPA8P5, AC007207.1, CCND2-AS1, CCND2, AC008012.1, TIGAR, AC006122.1, FGF23, FGF6, C12orf4, RAD51AP1, DYRK4, AC005832.2.
- chr12:7,166,674–11,895,377, 219 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
